Surgical pathology report (de-identified scan), TCGA case TCGA-SN-A84W, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site BLN - Baylor, specimen TCGA-SN-A84W-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

PATHOLOGIC DIAGNOSIS

TESTICLE, LEFT, RADICAL ORCHIECTOMY:

- MIXED GERM CELL TUMOR
- CLASSIC SEMINOMA 80%, MATURE TERATOMA 10%, EMBRYONAL CARCINOMA 5%, YOLK SAC TUMOR 5%
- 4.7 CM IN THE LARGEST DIMENSION
- INVASION INTO TUNICA VAGINALIS
- NO LYMPHOVASCULAR OR PERINEURAL INVASION
- MARGIN FREE
- INTRATUBULAR GERM CELL TUMOR

College of American Pathologist Synoptic Report:

Specimen type: Radical orchiectomy Serum tumor markers

Specimen laterality: Left HCG: 21

Tumor size (cm): 4.7 cm in the largest dimension LDH: 133

Macroscopic extent of tumor: Confined to the testis AFP: 6.5

Microscopic tumor extension: Invasion into tunica vaginalis

Histologic type: Seminoma, classic type; mature teratoma, embryonal carcinoma and yolk sac tumor

Lymphovascular invasion: Not seen

Primary tumor (T): pT2

Lymph node (N): NX

Distant metastasis (M): MX

Stage grouping: Stage IB

Site of distant metastasis: Not known

Surgical margins: Free

ICD-O-3
Mixed germ cell tumor 9085/3
Site @ Testis NOS C62.9
@ Testis NOS C62.9
JW 11/29/13

Comment: The findings were communicated via secure email with . and
at on

Staff Pathologist

Pertinent Clinical Information

History of left testicular mass.

Gross Description

[page 2 of 3]
Specimen Material: Left testicular mass.

Received fresh labeled "LEFT TESTICULAR MASS" is a testis (46 grams, 4.5 x 4.0 x 3.0 cm) with attached spermatic cord (11.0 x 1.0 cm).

The tunica vaginalis and lower spermatic cord are inked blue, and the testis is bisected to show two masses in the inferior pole. The larger mass (3.0 x 2.0 x 2.0 cm) is tan-white, friable, and focally hemorrhagic, with a bulging cut surface. The other mass (1.7 x 1.1 x 0.7 cm) has a tan-yellow, focally erythematous, solid cut surface. Both masses are well circumscribed and noncapsulated, and both appear confined to the testis. Both masses abut the tunica albuginea. A third possible mass (0.7 x 0.5 x 0.5 cm) is identified within the testicular parenchyma of the mid-superior pole. This third mass is located 1.1 cm from the nearest tunica albuginea, 1.7 cm from the epididymis and 12.0 cm from the spermatic cord margin (The largest mass is located 14.0 cm from the margin. The other inferior pole mass is located 13.0 cm from the margin). The remaining testicular parenchyma displays two foci of erythema in the superior pole which average 0.7 cm in greatest dimension. No other lesions are seen.

Representative sections are submitted:

- 1 - spermatic cord margin
- 2 - mid spermatic cord
- 3 - lower spermatic cord
- 4-5 - larger inferior pole mass to tunica vaginalis
- 6 - smaller inferior pole mass to tunica albuginea
- 7 - mid-superior pole mass to tunica albuginea
- 8 - grossly uninvolved testis and epididymis

Additional sections: 9-13 - tumor

Pathology Resident

Microscopic Description

c-Kit highlights the classic seminoma. Weak positivity is seen in the embryonal carcinoma.

Consult: concurs

The staff pathologist listed below has reviewed this case.

Pathology Resident

Electronically Signed Out

Staff Pathologist

*Pw TSS, dx discrepancy from statian
tumor to be 80% yolk sac + 20%
mature teratoma. BCR*

Reviewed	Am 11/5/13	Yes	No
Time Malignancy History			☒

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form 4.05

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Testicular Germ Cell Tumors - Cell Tumors)	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	M

Tumor Identifier Provided on Initial Case Quality Control Form	Provide the tumor identifier documented on the initial case quality control form for this case.	
Pathologic Diagnosis Provided on Initial Pathology Report	CLASSIC SEMINOMA 80%, MATURE TERATOMA 10%, EMBRYONAL CARCINOMA 5%, YOLK SAC TUMOR 5%	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
Histologic features of the sample provided for TCGA, as reflected on the CQCF	MATURE TERATOMA 20%, YOLK SAC TUMOR 80%	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.
Discrepancy between Pathology Report and Case Quality Control Form		
Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form	The tissue collected for research was taken from an area that was primarily Yolk Sac Tumor	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
Name of TSS Reviewing Pathologist or Biorepository Director	Provide the name of the pathologist who reviewed this case for TCGA.	

Source: NCI Genomic Data Commons file 32aa9858-297f-48b3-b3f5-4137c4e66ed3 (TCGA-SN-A84W.EE821F76-06CF-4701-B641-3FAA1006D416.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).